CCDI case PBCGDB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/862dfdce-c748-4f36-8cde-a429a2750ff8

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 14.5 years (5,285 days).

Biospecimens (3 samples)
- Samples 0DRSRU, 0DRSTY (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRSSA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
